Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3856, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3856-01A (Primary Tumor).

Diagnosis:

In I) II) a moderately differentiated invasive carcinoma of the colorectal type with penetration of all parietal layers and with vascular infiltration (G2, pT3, L1, V1), as well as free lymph nodes (0 of 13).

Tumor classification:

ICDO-DA M8140/3

G2, pT3, L1, V1, pN0 (0 of 13), locally R0

M classification in the context of the oncology conference

Source: NCI Genomic Data Commons file 5f4d10dc-7734-438f-b294-82026497dd11 (TCGA-AA-3856.9422F618-6EA5-49F3-9761-D176A5B59846.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).